Somatic mutation profile of tumor specimen MP2PRT-PAPPVN-TMP1-A (aliquot MP2PRT-PAPPVN-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPPVN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,081 days).
Specimen MP2PRT-PAPPVN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ca0df87-0197-463d-aa0f-affa1de141f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPPVN-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPPVN-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9917830b-ac5d-4e7e-93bd-9b14192afaac

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 37/339 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 109/380 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.5105A>G p.Q1702R | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as rs1567096629; called by muse, mutect2, varscan2
- C8orf48 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 141/340 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as rs543203990, COSV52046472; called by muse, mutect2, varscan2
- DMBT1 | c.5510G>A p.R1837H (on ENST00000338354 / NM_001377530.1; = p.R1080H on NM_004406.3) | Missense Mutation (SNP) | VAF 64/585 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs748198152, COSV57537993; called by muse, mutect2, varscan2
- DST | c.22193G>A p.R7398H (on ENST00000361203 / NM_001374722.1; = p.R5108H on NM_015548.5) | Missense Mutation (SNP) | VAF 155/483 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369312019; called by muse, mutect2, varscan2
- GPR75 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746727233; called by muse, mutect2, varscan2
- PCDHA13 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 166/383 reads (43%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs782439110, COSV56489639; called by muse, mutect2, varscan2
- RXFP4 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 25/603 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV100563546; called by muse, mutect2
- SCN7A | c.2545G>T p.D849Y | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV69270873; called by muse, mutect2, varscan2
- SH3RF2 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373327542; called by muse, mutect2, varscan2
- ANKRD26 | c.13T>A p.F5I | Missense Mutation (SNP) | VAF 298/462 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- GATA6 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 56/900 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2
- TNKS | c.2421G>C p.L807F | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AL645922.1 | c.2229C>T p.T743= | Silent (SNP) | VAF 31/533 reads (6%) | called by muse, mutect2
- EFCAB6 | c.3798C>T p.D1266= | Silent (SNP) | VAF 154/328 reads (47%) | catalogued as rs144783076; called by muse, mutect2, varscan2
- KCNQ3 | c.1623C>T p.Y541= | Silent (SNP) | VAF 100/249 reads (40%) | catalogued as rs138900075; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF25 | c.1068C>T p.F356= (on ENST00000354419 / NM_030615.2; = p.F304= on NM_005355.3) | Silent (SNP) | VAF 131/613 reads (21%) | catalogued as rs770880704, COSV63027562; called by muse, mutect2, varscan2
- PAPPA2 | c.1653C>T p.H551= | Silent (SNP) | VAF 104/538 reads (19%) | catalogued as rs771412206, COSV62777360; called by muse, mutect2, varscan2
- RBFOX1 | c.867G>A p.P289= | Silent (SNP) | VAF 127/430 reads (30%) | catalogued as rs745729142; called by muse, mutect2, varscan2
- CNTNAP3P2 | n.164C>G | RNA (SNP) | VAF 145/577 reads (25%) | called by muse, mutect2
- MARVELD3 | chr16:71640490 C>T | 3'Flank (SNP) | VAF 194/326 reads (60%) | catalogued as rs372495610; called by muse, mutect2, varscan2
